CCDI case PBCJSE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d2c61fbf-061a-4e36-8b63-6b8f96760ee7

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,055 days).

Biospecimens (3 samples)
- Sample 0DTLG9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTLGE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTLGJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
